Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3GY, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3GY-01A (Primary Tumor).

Surgical Pathology Report

Department of Pathology,

DOB:

Sex: r

Physician:

Accession:

Collected: _____

Received: _____

Case type: Surgical Case

DIAGNOSIS

(A) TOTAL THYROIDECTOMY:

PAPILLARY CARCINOMA OF THYROID RIGHT LOBE (1.5 CM) TUMOR CONFINED TO THE THYROID GLAND.
MARGINS FREE.

METASTATIC PAPILLARY CARCINOMA IN ONE OF TWO PERITHYROIDAL LYMPH NODES.

Entire report and diagnosis completed by

1CD-0-3

carcinoma, papillary, thyroid 826013
Site: thyroid, NOS CT3.4 fw 11/30/11

GROSS DESCRIPTION

(A) TOTAL THYROIDECTOMY - A total thyroidectomy specimen consisting of right lobe (4.5 x 2.5 x 1.8), isthmus (1.0 x 1.0 x 0.3 cm), and left lobe (3.0 x 2.0 x 0.8 cm). Both lobes are sectioned from the superior to inferior aspect. The inferior pole at the right lobe shows encapsulated brown-tan soft tissue measuring 1.3 x 1.0 cm. Both isthmus and the left lobe are unremarkable. A tissue sample of the tumor as well as of the left lobe are taken for the tumor bank.

SECTION CODE: A1-A6, entire lobe from superior to inferior (A4-A5, including tumor); A7, isthmus, in toto; A8, A9, remnant of left lobe.

CLINICAL HISTORY

History of thyroid mass.

SNOMED CODES

T-B6000, M-80503

"Some tests reported here may have been developed and performance characteristics determined by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or approved

Released by:

Source: NCI Genomic Data Commons file ce345a9a-7c3e-4611-a860-88584cc1a0fb (TCGA-EL-A3GY.F7DBE537-2DDB-4C7D-926D-D6BBCA653006.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).